Somatic mutation profile of tumor specimen TCGA-B8-4619-01A (aliquot TCGA-B8-4619-01A-02D-1553-08) from TCGA case TCGA-B8-4619, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.1 years (21,206 days).
Specimen TCGA-B8-4619-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e916499-d002-468c-b45e-54bcfdca59dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-4619-10A (Blood Derived Normal), aliquot TCGA-B8-4619-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c3b22ab-4889-4c59-8cd2-ab303300a157

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD2B | c.4250T>G p.V1417G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99477846; called by muse, mutect2, varscan2
- ATP1A2 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs779812635, COSV63402362, COSV63403685; called by muse, mutect2, varscan2
- GRIN2B | c.4108G>A p.G1370R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as rs754738111, COSV74207152; called by muse, mutect2, varscan2
- MAP1B | c.7248G>A p.M2416I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV99702516; called by muse, mutect2, varscan2
- NEIL1 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV99145469; called by muse, mutect2, varscan2
- PTPRZ1 | c.1109A>T p.D370V | Missense Mutation (SNP) | VAF 75/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101100237; called by muse, mutect2, varscan2
- PYGM | c.2202T>G p.D734E | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99377206; called by muse, mutect2, varscan2
- RPH3A | c.245G>A p.R82H (on ENST00000389385 / NM_001143854.2; = p.R78H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs141736304, COSV66992865; called by muse, mutect2, varscan2
- RRBP1 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.953); catalogued as COSV99854160; called by muse, mutect2, varscan2
- SAG | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101300676; called by muse, mutect2, varscan2
- ZNF214 | c.130A>C p.N44H | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99547450; called by muse, mutect2, varscan2
- ZNF320 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as COSV101206877; called by muse, mutect2, varscan2
- ZNF782 | c.314del p.L105Yfs*7 | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | called by mutect2, pindel, varscan2
- GPR107 | c.1662C>T p.Y554= (on ENST00000372406 / NM_001136557.2; = p.Y506= on NM_020960.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/267 reads (31%) | catalogued as COSV100714682; called by muse, mutect2, varscan2
- DOCK4 | c.3402-158G>T | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as COSV101312831; called by muse, mutect2, varscan2
